CCDI case PBCCRU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/ab79b60a-bfd7-4fd8-953f-102ff23c9e41

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 3.1 years (1,130 days).

Biospecimens (2 samples)
- Sample 0DOV8L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOV9J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
